Somatic mutation profile of tumor specimen SM-JU333 (aliquot 7316UP-426) from CPTAC case C298152, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU333: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aab699a0-5867-4fa7-9176-e56b4c94b334.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105208 (Blood Derived Normal), aliquot 7316UP-426-1105208; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb4ae9db-5c7f-4278-adef-cd49ea400308

The open-access MAF lists 40 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 10, Nonsense Mutation 1, Intron 1, 5'UTR 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 102/188 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs864622341, COSV64290156; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- USH2A | c.10450C>T p.R3484* | Nonsense Mutation (SNP) | VAF 40/91 reads (44%) | catalogued as rs111033379, CM080610, COSV56427899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs779902900, COSV60922721; called by muse, mutect2, varscan2
- CPAMD8 | c.1474G>A p.G492S (on ENST00000651564; = p.G445S on NM_015692.5) | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs574048580; called by muse, mutect2, varscan2
- CPZ | c.1862C>T p.A621V (on ENST00000360986 / NM_001014447.3; = p.A610V on NM_003652.3) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs201930593, COSV100249106; called by muse, mutect2, varscan2
- DDX43 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 60/519 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.086); catalogued as COSV100946485, COSV64836729; called by muse, mutect2, varscan2
- JPH1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs748452859, COSV60608792; called by muse, mutect2, varscan2
- MTHFR | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775829502, COSV100928224; called by muse, mutect2
- MUC5B | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs554624154; called by muse, mutect2, varscan2
- NPNT | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs778565408, COSV59753816; called by muse, mutect2, varscan2
- OBSCN | c.13361C>T p.T4454M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs758896862, COSV52750133, COSV52751888; called by muse, mutect2
- PCLO | c.8125C>A p.H2709N | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV61653611; called by muse, mutect2, varscan2
- PLCG1 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54814695; called by muse, mutect2, varscan2
- RELB | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 113/315 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); catalogued as rs571786771, COSV55513078; called by muse, mutect2, varscan2
- RGS9 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 166/495 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs913010766, COSV52225932; called by muse, mutect2, varscan2
- SIPA1L3 | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 100/288 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs370319919; called by muse, mutect2, varscan2
- SLC9C1 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV59885674; called by muse, mutect2
- TRPV6 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs775866936; called by muse, mutect2, varscan2
- WDR88 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.32); catalogued as rs201611292; called by muse, mutect2, varscan2
- AKAP9 | c.5905C>A p.Q1969K (on ENST00000359028; = p.Q1937K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/388 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- BTN3A3 | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EML3 | c.1074C>A p.F358L | Missense Mutation (SNP) | VAF 91/314 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR52B4 | c.769G>C p.G257R | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PABPN1 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 86/496 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGB5 | c.397T>A p.F133I | Missense Mutation (SNP) | VAF 98/325 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRRAP | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADIPOQ | c.624C>T p.G208= | Silent (SNP) | VAF 113/219 reads (52%) | catalogued as rs200876636; called by muse, mutect2, varscan2
- APBB1 | c.30G>A p.S10= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs777578946; called by muse, mutect2
- CNTNAP2 | c.2037C>T p.A679= | Silent (SNP) | VAF 131/543 reads (24%) | catalogued as rs539741829, COSV62276109; called by muse, mutect2, varscan2
- CPNE4 | c.93G>A p.A31= | Silent (SNP) | VAF 67/279 reads (24%) | catalogued as rs368853915, COSV70193650; called by muse, mutect2, varscan2
- FAM83H | c.1992G>A p.K664= | Silent (SNP) | VAF 124/363 reads (34%) | called by muse, mutect2, varscan2
- FTCD | c.1479C>T p.G493= | Silent (SNP) | VAF 172/591 reads (29%) | catalogued as rs576503541, COSV52430942; called by muse, mutect2, varscan2
- GABRD | c.153C>T p.Y51= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as rs148496176; called by muse, mutect2, varscan2
- RAB6C | c.606C>T p.S202= | Silent (SNP) | VAF 84/315 reads (27%) | catalogued as COSV101308492; called by muse, mutect2, varscan2
- TSBP1 | c.495C>T p.H165= (on ENST00000617061; = p.P175S on NM_006781.5) | Silent (SNP) | VAF 50/191 reads (26%) | called by muse, mutect2
- ZNF461 | c.1368C>T p.L456= | Silent (SNP) | VAF 14/277 reads (5%) | catalogued as COSV64452884, COSV64455033; called by muse, mutect2
- AC058822.1 | c.1018-288066G>C | Intron (SNP) | VAF 50/139 reads (36%) | called by muse, mutect2, varscan2
- GNL1 | c.-940C>T | 5'UTR (SNP) | VAF 153/422 reads (36%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159896 G>A | 5'Flank (SNP) | VAF 22/78 reads (28%) | catalogued as rs1413811503; called by muse, mutect2
- SNORD116-6 | n.84G>A | RNA (SNP) | VAF 73/207 reads (35%) | catalogued as rs756590960; called by muse, mutect2, varscan2
